Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A032, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A032-01A (Primary Tumor).

Findings and diagnosis relating to the problem concerned:

This is an invasive adenocarcinoma of the colon in the position of the rectum (rectal carcinoma, G2) with infiltration of all parietal layers (pT3), with vascular invasion (L1, V1), with free oral and aboral resection margins, as well as a free resection margin toward the central region and two lymph node metastases (pN1).

Tumor classification:

ICDO-DA M-8140/3

G2

pT3, L1, V1, pN1.

Reviewed with:	5/10/11	

ICD-O-3
adenocarcinoma, NOS 8140/3
Site: Rectum c20.9 for 4/11

✓

Source: NCI Genomic Data Commons file c389bba9-e6ba-437e-ab57-939ddb98c1ee (TCGA-AG-A032.ED971B39-F5BD-4414-9E09-C6D993422941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).